Gene-level copy-number profile of tumor specimen C3L-03961-02 from CPTAC case C3L-03961, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 48.6 years (17,760 days).
Specimen C3L-03961-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 36689dd6-811a-4ff2-b1cb-0e84c52d14b2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03961-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/cc87ef7c-167f-46a8-94c9-6d683607c2e4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 14,309; copy number 2: 38,509; copy number 3: 3,274; copy number 4: 2,226; copy number 5: 64; copy number 6: 11; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:41,340,823–41,355,538, 1 gene: CDRT15P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 76 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:123,323,422–128,320,214, 75 genes, copy number 5–6 (broad region; genes not listed).
- chr21:12,999,676–13,016,692, 1 gene, copy number 7: AP001464.1.

Autosomal genes at a single copy (total copy number 1): 11,965. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
